Somatic mutation profile of tumor specimen MP2PRT-PAUJFA-TMP1-A (aliquot MP2PRT-PAUJFA-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PAUJFA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (987 days).
Specimen MP2PRT-PAUJFA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7dd3746-252f-4e8e-bb0e-a6b5c347c3b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJFA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJFA-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89a36462-4351-42b9-aa90-379b9964b087

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH5 | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 16/219 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750874924, COSV59752526; called by muse, mutect2
- NMRK2 | c.556G>C p.D186H | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV51454746; called by muse, mutect2
- NRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 36/272 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV65731978; called by muse, mutect2, varscan2
- TSPEAR | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 33/365 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.146); catalogued as rs1281531743; called by muse, mutect2
- USP20 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 31/466 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs1390765765; called by muse, mutect2
- ATRX | c.2381A>T p.K794M | Missense Mutation (SNP) | VAF 83/276 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- EIF5B | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FSIP2 | c.16645G>A p.D5549N | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.111); called by muse, mutect2
- HECTD4 | c.9936A>T p.K3312N | Missense Mutation (SNP) | VAF 17/372 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C5AR2 | c.70C>T p.L24= | Silent (SNP) | VAF 47/502 reads (9%) | called by muse, mutect2
- CDH17 | c.2427C>T p.R809= | Silent (SNP) | VAF 12/260 reads (5%) | called by muse, mutect2
- FBXL6 | c.969G>A p.L323= | Silent (SNP) | VAF 70/341 reads (21%) | called by muse, mutect2, varscan2
- SLC49A3 | c.852C>T p.S284= (on ENST00000404286 / NM_001294341.2; = p.S283= on NM_032219.4) | Silent (SNP) | VAF 76/322 reads (24%) | catalogued as rs149591230; called by muse, mutect2, varscan2
